Somatic mutation profile of tumor specimen TCGA-EJ-5542-01A (aliquot TCGA-EJ-5542-01A-01D-1576-08) from TCGA case TCGA-EJ-5542, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.1 years (21,942 days).
Specimen TCGA-EJ-5542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e347272-b337-439c-b546-29191f2135e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5542-10A (Blood Derived Normal), aliquot TCGA-EJ-5542-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05351dbc-d278-48fe-aa60-71a1c4100f78

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD26 | c.2219A>G p.E740G | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV65776882; called by muse, mutect2
- CMA1 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as COSV51626036; called by muse, mutect2, varscan2
- DMRT2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201585505, COSV52402687; called by muse, mutect2
- DOCK2 | c.4357G>A p.V1453I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs749664205, COSV56973731; called by muse, mutect2, varscan2
- EXD3 | c.1732G>C p.D578H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59810301; called by muse, mutect2
- EXTL3 | c.1841T>C p.F614S | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV55037122; called by muse, mutect2
- FAT4 | c.6876C>G p.N2292K | Missense Mutation (SNP) | VAF 123/570 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58698530; called by muse, mutect2, varscan2
- FBLIM1 | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV60030740; called by muse, mutect2, varscan2
- FBN1 | c.2393A>G p.Y798C | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1064793112, CM154805, COSV57324631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LOXL2 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV66692573; called by muse, mutect2, varscan2
- MCL1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs367658301, COSV100329496; called by muse, mutect2, varscan2
- MPEG1 | c.945C>A p.N315K | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV57093198; called by muse, mutect2, varscan2
- PRG3 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV54664202; called by muse, mutect2, varscan2
- PTPN21 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60850290; called by muse, mutect2, varscan2
- ZMYND12 | c.899A>C p.D300A | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV65342336; called by muse, mutect2
- ZNF521 | c.3253A>G p.I1085V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV64129628; called by muse, mutect2
- IGKV1-17 | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- PRAMEF8 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.884); called by muse, mutect2
- ZNF292 | c.1788_1792del p.S596Rfs*23 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- FGG | c.372A>G p.A124= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV60196103; called by muse, mutect2, varscan2
- GRIK5 | c.105G>A p.V35= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV53482318; called by muse, mutect2
- GSDMB | c.987G>A p.A329= (on ENST00000418519 / NM_001165958.1; = p.A307= on NM_018530.2) | Silent (SNP) | VAF 84/283 reads (30%) | catalogued as rs144949338; called by muse, mutect2, varscan2
- KLHL3 | c.1581G>A p.R527= | Silent (SNP) | VAF 25/273 reads (9%) | catalogued as COSV59056211; called by muse, mutect2
- MLLT1 | c.1299G>A p.R433= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1031237625, COSV53131974; called by muse, mutect2
- NLRC3 | c.1767C>T p.S589= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1316023084, COSV57086432; called by muse, mutect2
- SMG6 | c.3177G>A p.S1059= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs751108862, COSV53971759; called by muse, mutect2, varscan2
- NACA | c.71-3594A>G | Intron (SNP) | VAF 38/126 reads (30%) | catalogued as COSV63271398; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792648 T>G | 3'Flank (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
